Somatic mutation profile of tumor specimen TCGA-DW-7837-01A (aliquot TCGA-DW-7837-01A-11D-2136-08) from TCGA case TCGA-DW-7837, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 43.5 years (15,891 days).
Specimen TCGA-DW-7837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b34761d4-ce5e-4797-9765-e635257a3141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7837-10A (Blood Derived Normal), aliquot TCGA-DW-7837-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3511e5df-3e27-4f89-a44c-700a832d8c26

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL1 | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV54418865; called by muse, mutect2, varscan2
- CCDC174 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57982300; called by muse, mutect2, varscan2
- CLASP1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55340333; called by muse, mutect2, varscan2
- CLU | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57066805, COSV57068357; called by muse, mutect2, varscan2
- DDX60L | c.2653C>T p.L885F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs749721848, COSV52721853; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.63); catalogued as COSV50053398; called by muse, mutect2, varscan2
- EVPL | c.3931A>C p.K1311Q | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV56916104; called by muse, mutect2, varscan2
- GPT | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52954828; called by muse, mutect2, varscan2
- KAT6A | c.3796A>C p.K1266Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.852); catalogued as COSV55911960; called by muse, mutect2, varscan2
- MEGF8 | c.4894T>C p.S1632P (on ENST00000251268 / NM_001271938.2; = p.S1565P on NM_001410.3) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99239193; called by mutect2, varscan2
- NCOR1 | c.7171C>G p.R2391G | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV51995940, COSV51997682; called by muse, mutect2, varscan2
- PRPF18 | c.826A>G p.N276D | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60726189; called by muse, mutect2, varscan2
- RAB11A | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV56042977; called by muse, mutect2, varscan2
- RSPRY1 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368309991; called by muse, mutect2, varscan2
- TRPC4AP | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV52684523; called by muse, mutect2, varscan2
- ZNF385B | c.1242A>T p.A414= | Splice Region (SNP) | VAF 66/223 reads (30%) | catalogued as COSV61181614; called by muse, mutect2, varscan2
- CUBN | c.7120dup p.Y2374Lfs*7 | Frame Shift Ins (INS) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- DNAJC16 | c.1417_1418del p.S473* | Frame Shift Del (DEL) | VAF 66/297 reads (22%) | called by pindel, varscan2
- PTPRCAP | c.538_551del p.L180Wfs*7 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.3552C>G p.A1184= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55238107; called by muse, mutect2, varscan2
- FASN | c.276C>T p.D92= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs568118566, COSV60761088; called by mutect2, varscan2
- KCNQ2 | c.321C>G p.L107= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as rs757187562, COSV60435079; called by muse, mutect2, varscan2
- MAP3K1 | c.2307T>A p.P769= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV68127411; called by muse, mutect2, varscan2
- NLRP5 | c.1473C>T p.V491= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs765298030, COSV66767355, COSV66767456; called by muse, mutect2, varscan2
- TRIM24 | c.141G>A p.A47= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1265856627, COSV58978193; called by muse, mutect2, varscan2
